Somatic mutation profile of tumor specimen C3L-04083-02 (aliquot CPT0242430007) from CPTAC case C3L-04083, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 60.0 years (21,910 days).
Specimen C3L-04083-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Frontal Lobe; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e71ad976-8cc4-4003-8268-c596a26ac419.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-04083-31 (Blood Derived Normal), aliquot CPT0243420002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fff9dd03-5964-405a-b9cd-6f354eec3480

The open-access MAF lists 90 somatic variants for this specimen: 57 protein-altering or splice-affecting, 22 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, Silent 22, Intron 8, Nonsense Mutation 5, Splice Site 4, RNA 2, Frame Shift Del 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.278A>G p.H93R | Missense Mutation (SNP) | VAF 46/77 reads (60%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs121909238, CM051214, COSV100910602, COSV64296545, COSV64296755; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ARNTL | c.1699T>A p.S567T (on ENST00000403290 / NM_001297719.2; = p.S566T on NM_001178.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/116 reads (28%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.708); catalogued as COSV53401659; called by muse, mutect2, varscan2
- CDX4 | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 96/291 reads (33%) | catalogued as COSV65171416; called by muse, mutect2, varscan2
- CFAP54 | c.3596G>A p.S1199N | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.196); catalogued as rs1375417093; called by muse, mutect2, varscan2
- CNTNAP3 | c.3062G>T p.S1021I | Missense Mutation (SNP) | VAF 28/499 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.04); catalogued as COSV52669916; called by muse, mutect2
- CRAMP1 | c.2843C>T p.T948M | Missense Mutation (SNP) | VAF 66/255 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); catalogued as rs766372583; called by muse, mutect2, varscan2
- CYP4X1 | c.737G>A p.R246H | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.118); catalogued as rs530490572, COSV64149524; called by muse, mutect2, varscan2
- DCAF12L1 | c.842C>T p.S281F | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as rs267606338, COSV64421993; called by muse, mutect2, varscan2
- FBN2 | c.3163G>A p.G1055R | Missense Mutation (SNP) | VAF 193/467 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); catalogued as rs1372203787; called by muse, mutect2, varscan2
- HSD17B3 | c.901G>T p.A301S | Missense Mutation (SNP) | VAF 221/610 reads (36%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as COSV100931237; called by muse, mutect2, varscan2
- MEGF8 | c.8290C>T p.R2764* (on ENST00000251268 / NM_001271938.2; = p.R2697* on NM_001410.3) | Nonsense Mutation (SNP) | VAF 95/253 reads (38%) | catalogued as rs1290482229; called by muse, mutect2, varscan2
- MISP | c.479C>T p.T160M | Missense Mutation (SNP) | VAF 67/542 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.213); catalogued as rs374036064; called by muse, mutect2, varscan2
- MYH2 | c.3359G>A p.R1120H | Missense Mutation (SNP) | VAF 160/451 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.957); catalogued as rs752746936, COSV55433509; called by muse, mutect2, varscan2
- MYO15A | c.10082+1G>T p.X3361_splice | Splice Site (SNP) | VAF 168/500 reads (34%) | catalogued as rs772568482; called by muse, mutect2, varscan2
- NALCN | c.5011C>T p.R1671C | Missense Mutation (SNP) | VAF 136/228 reads (60%) | SIFT deleterious (0.02); PolyPhen benign (0.445); catalogued as rs143587652; called by muse, mutect2, varscan2
- NDUFS1 | c.896G>A p.R299H | Missense Mutation (SNP) | VAF 47/158 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.576); catalogued as rs137994727; called by muse, mutect2, varscan2
- NLRP5 | c.1933G>A p.V645I | Missense Mutation (SNP) | VAF 62/164 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.053); catalogued as rs369519846, COSV66762308; called by muse, mutect2, varscan2
- OR13C3 | c.793C>T p.R265C | Missense Mutation (SNP) | VAF 53/143 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.035); catalogued as rs369932733; called by muse, mutect2, varscan2
- OR4C6 | c.59A>G p.E20G | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.071); catalogued as rs1440105895; called by mutect2, varscan2
- OR6V1 | c.508G>C p.D170H | Missense Mutation (SNP) | VAF 150/596 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.023); catalogued as COSV101389239; called by muse, mutect2, varscan2
- PABPC5 | c.55G>A p.A19T | Missense Mutation (SNP) | VAF 46/122 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.167); catalogued as COSV57040607; called by muse, mutect2, varscan2
- PLXNA3 | c.4075C>T p.R1359C | Missense Mutation (SNP) | VAF 150/502 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs150035406; called by muse, mutect2, varscan2
- POTEH | c.1423A>G p.T475A | Missense Mutation (SNP) | VAF 102/927 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs377249151; called by muse, varscan2
- PPP2R1B | c.1370C>T p.S457F | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.063); catalogued as COSV59534618; called by muse, mutect2, varscan2
- ROR2 | c.323G>A p.R108Q | Missense Mutation (SNP) | VAF 201/562 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65216235, COSV65222255; called by muse, mutect2, varscan2
- SLC9C1 | c.3191G>A p.R1064Q | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.031); catalogued as rs377402243; called by muse, mutect2, varscan2
- SYNE3 | c.1931G>A p.R644Q | Missense Mutation (SNP) | VAF 17/128 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs761524122; called by muse, mutect2, varscan2
- SYT6 | c.270C>G p.N90K (on ENST00000610222 / NM_001366225.1; = p.N5K on NM_205848.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as COSV65773413; called by muse, mutect2, varscan2
- TDRD5 | c.1006T>A p.L336I | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.389); catalogued as COSV54244050; called by muse, mutect2
- UMODL1 | c.3391G>A p.V1131M (on ENST00000408910 / NM_001004416.2; = p.V1259M on NM_173568.3) | Missense Mutation (SNP) | VAF 114/357 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs373290786; called by muse, mutect2, varscan2
- USP9X | c.7490A>G p.D2497G | Missense Mutation (SNP) | VAF 82/272 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.071); catalogued as COSV100199910; called by muse, mutect2, varscan2
- VSIG10L | c.2078G>A p.R693H | Missense Mutation (SNP) | VAF 50/131 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs959599620; called by muse, mutect2, varscan2
- XAB2 | c.1382C>T p.A461V | Missense Mutation (SNP) | VAF 88/271 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.023); catalogued as rs367588563; called by muse, mutect2, varscan2
- ZNF628 | c.2555C>T p.T852I | Missense Mutation (SNP) | VAF 204/557 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs762448718; called by muse, mutect2, varscan2
- CBLL2 | c.1165A>T p.R389W | Missense Mutation (SNP) | VAF 62/188 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- CDC42BPB | c.264_267del p.E89Lfs*6 | Frame Shift Del (DEL) | VAF 30/107 reads (28%) | called by mutect2, pindel, varscan2
- CYP27C1 | c.137T>G p.V46G | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DCLK3 | c.1314C>A p.D438E | Missense Mutation (SNP) | VAF 130/379 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DSC1 | c.1520+1G>T p.X507_splice | Splice Site (SNP) | VAF 12/69 reads (17%) | called by muse, mutect2, varscan2
- ESPN | c.667G>A p.V223M | Missense Mutation (SNP) | VAF 87/229 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- FCHO1 | c.1351+1G>A p.X451_splice | Splice Site (SNP) | VAF 102/246 reads (41%) | called by muse, mutect2, varscan2
- FRMD1 | c.256G>A p.V86M | Missense Mutation (SNP) | VAF 128/383 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- GOLGB1 | c.4907T>A p.V1636E | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- HIBCH | c.538G>T p.G180* | Nonsense Mutation (SNP) | VAF 23/140 reads (16%) | called by muse, mutect2, varscan2
- IFT88 | c.688C>T p.Q230* (on ENST00000319980 / NM_001318493.2; = p.Q221* on NM_006531.5 and 9 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 8/43 reads (19%) | called by muse, mutect2, varscan2
- KHDC4 | c.681+1G>A p.X227_splice | Splice Site (SNP) | VAF 97/287 reads (34%) | called by muse, mutect2, varscan2
- NCOA1 | c.1048C>G p.Q350E | Missense Mutation (SNP) | VAF 39/150 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- NLRP4 | c.292A>T p.T98S | Missense Mutation (SNP) | VAF 43/109 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- NR4A2 | c.1495G>T p.D499Y | Missense Mutation (SNP) | VAF 115/375 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PIEZO2 | c.7031T>A p.L2344* | Nonsense Mutation (SNP) | VAF 43/101 reads (43%) | called by muse, mutect2, varscan2
- PNMA3 | c.1189G>A p.V397M | Missense Mutation (SNP) | VAF 71/163 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- RSPO4 | c.241C>T p.R81C | Missense Mutation (SNP) | VAF 128/394 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- THEMIS | c.890C>T p.P297L | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- TRPC7 | c.1700C>T p.P567L | Missense Mutation (SNP) | VAF 114/342 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF267 | c.1361A>T p.H454L | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.619); called by muse, mutect2, varscan2
- ZNF287 | c.959del p.N320Ifs*8 | Frame Shift Del (DEL) | VAF 11/37 reads (30%) | called by mutect2, pindel, varscan2
- ZNF717 | c.1931A>T p.E644V | Missense Mutation (SNP) | VAF 26/154 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.56); called by muse, mutect2
- ABCC12 | c.1893G>A p.S631= | Silent (SNP) | VAF 125/331 reads (38%) | catalogued as rs150180336, COSV60915138; called by muse, mutect2, varscan2
- AMER2 | c.1776C>T p.I592= | Silent (SNP) | VAF 40/71 reads (56%) | called by muse, mutect2, varscan2
- BANP | c.1479C>T p.A493= (on ENST00000286122; = p.A443= on NM_017869.4) | Silent (SNP) | VAF 74/185 reads (40%) | catalogued as rs111350348, COSV53739879; called by muse, mutect2, varscan2
- BTNL8 | c.105C>T p.D35= | Silent (SNP) | VAF 14/163 reads (9%) | catalogued as rs371053690; called by muse, mutect2
- CTAGE1 | c.9C>T p.P3= | Silent (SNP) | VAF 32/89 reads (36%) | catalogued as COSV101194459, COSV66943287; called by muse, mutect2, varscan2
- ENGASE | c.336G>A p.A112= | Silent (SNP) | VAF 182/512 reads (36%) | catalogued as rs368771548, COSV56134442; called by muse, mutect2, varscan2
- FCN1 | c.27C>A p.A9= | Silent (SNP) | VAF 74/278 reads (27%) | catalogued as COSV100878842; called by muse, mutect2, varscan2
- FGFR3 | c.1032A>T p.I344= | Silent (SNP) | VAF 60/285 reads (21%) | called by muse, mutect2, varscan2
- FSCB | c.1488T>G p.S496= | Silent (SNP) | VAF 47/173 reads (27%) | catalogued as rs1469628510; called by muse, mutect2, varscan2
- GDPD5 | c.288T>G p.A96= | Silent (SNP) | VAF 60/191 reads (31%) | called by muse, mutect2, varscan2
- GLUD2 | c.1149C>A p.A383= | Silent (SNP) | VAF 79/461 reads (17%) | called by muse, mutect2, varscan2
- GOLGA6L22 | c.1326C>T p.H442= | Silent (SNP) | VAF 78/479 reads (16%) | catalogued as rs540713057, COSV57031937; called by muse, varscan2
- IL1RL1 | c.621C>A p.G207= | Silent (SNP) | VAF 13/68 reads (19%) | called by muse, mutect2, varscan2
- KCNH2 | c.1782C>T p.G594= | Silent (SNP) | VAF 100/685 reads (15%) | called by muse, mutect2, varscan2
- NEB | c.16143T>C p.D5381= | Silent (SNP) | VAF 12/32 reads (38%) | called by muse, mutect2, varscan2
- NEDD4 | c.1290T>C p.D430= | Silent (SNP) | VAF 18/50 reads (36%) | called by muse, mutect2, varscan2
- RASSF9 | c.213G>A p.L71= | Silent (SNP) | VAF 40/101 reads (40%) | called by muse, mutect2, varscan2
- SBK2 | c.408G>A p.L136= | Silent (SNP) | VAF 22/454 reads (5%) | called by muse, mutect2
- SNX20 | c.813C>T p.D271= | Silent (SNP) | VAF 87/239 reads (36%) | catalogued as rs750413433, COSV56057562; called by muse, mutect2, varscan2
- TAF5L | c.327A>G p.Q109= | Silent (SNP) | VAF 56/143 reads (39%) | called by muse, mutect2, varscan2
- TSPYL4 | c.255G>C p.A85= | Silent (SNP) | VAF 12/80 reads (15%) | called by muse, mutect2, varscan2
- UBTF | c.627C>T p.H209= | Silent (SNP) | VAF 42/116 reads (36%) | catalogued as rs766881272; called by muse, mutect2, varscan2
- AC133561.1 | n.1548G>A | RNA (SNP) | VAF 45/195 reads (23%) | catalogued as rs575258996; called by muse, mutect2, varscan2
- ARHGAP22 | c.989-296G>C | Intron (SNP) | VAF 59/151 reads (39%) | called by muse, mutect2, varscan2
- COL5A1 | c.654+7595G>A | Intron (SNP) | VAF 155/441 reads (35%) | catalogued as rs958658767; called by muse, mutect2, varscan2
- FAM117A | c.367-1847G>A | Intron (SNP) | VAF 98/303 reads (32%) | catalogued as rs1486798219; called by muse, mutect2, varscan2
- FAM227B | c.1013-24636T>C | Intron (SNP) | VAF 12/74 reads (16%) | called by mutect2, varscan2
- GLYATL1 | n.369G>A | RNA (SNP) | VAF 70/206 reads (34%) | called by muse, mutect2, varscan2
- HBE1 | c.-267+102757G>A | Intron (SNP) | VAF 42/83 reads (51%) | catalogued as rs1192698796; called by muse, mutect2
- LDLRAD1 | c.-6G>A | 5'UTR (SNP) | VAF 43/96 reads (45%) | catalogued as rs373433016; called by muse, mutect2, varscan2
- OBSCN | c.18662-2219G>A | Intron (SNP) | VAF 104/257 reads (40%) | catalogued as rs374982677, COSV52788551; called by muse, mutect2, varscan2
- TRPS1 | c.-2-3573C>G | Intron (SNP) | VAF 26/69 reads (38%) | called by muse, mutect2, varscan2
- WDR86 | c.163+448T>C | Intron (SNP) | VAF 194/432 reads (45%) | called by muse, mutect2, varscan2
